Somatic mutation profile of tumor specimen TCGA-27-1830-01A (aliquot TCGA-27-1830-01A-01D-1494-08) from TCGA case TCGA-27-1830, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.9 years (21,131 days).
Specimen TCGA-27-1830-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68923a67-0869-45b3-802c-e7cf4abc6344.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1830-10A (Blood Derived Normal), aliquot TCGA-27-1830-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59cf743e-2e9d-4828-ba83-3bbf1e230962

The open-access MAF lists 48 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 3, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 56/98 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VWF | c.4696C>T p.R1566* | Nonsense Mutation (SNP) | VAF 25/146 reads (17%) | catalogued as rs61750112, CM061230, COSV54613751; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CABS1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs758926757, COSV56733074; called by muse, mutect2, varscan2
- CD163L1 | c.2686+1G>A p.X896_splice | Splice Site (SNP) | VAF 48/172 reads (28%) | catalogued as rs193151180, CS153145; called by muse, mutect2, varscan2
- CHST6 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.333); catalogued as COSV59999636; called by muse, mutect2, varscan2
- CR2 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65506380; called by muse, mutect2, varscan2
- DCUN1D4 | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV58121306; called by muse, mutect2, varscan2
- DNAH5 | c.5562A>T p.K1854N | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1382216248, COSV54210122; called by muse, mutect2, varscan2
- DSG3 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768429518, COSV57124793; called by muse, mutect2, varscan2
- EPHA5 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1439259258, COSV56633589, COSV56640546; called by muse, mutect2, varscan2
- FAM135B | c.776T>C p.F259S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV52711359; called by muse, mutect2
- FUT6 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs746832241, COSV99744667; called by muse, mutect2, varscan2
- IFI35 | c.811G>A p.V271I (on ENST00000415816 / NM_001330230.2; = p.V273I on NM_005533.5) | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs375429330; called by muse, mutect2, varscan2
- IRAK3 | c.155G>A p.W52* | Nonsense Mutation (SNP) | VAF 42/114 reads (37%) | catalogued as COSV54160005; called by muse, mutect2, varscan2
- JPH2 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs750791531, COSV65902250; called by muse, mutect2, varscan2
- MSH4 | c.1968A>T p.K656N | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV54198194; called by muse, mutect2, varscan2
- MYLK | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as rs761508149, COSV60606293; called by muse, mutect2, varscan2
- OR8U1 | c.19A>T p.T7S | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs1384096192, COSV100163938; called by muse, mutect2
- PCBP3 | c.795C>A p.P265= | Splice Region (SNP) | VAF 37/172 reads (22%) | catalogued as COSV68406926; called by muse, mutect2, varscan2
- PKHD1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs374645464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA4 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 94/506 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs774798274, COSV58110834; called by muse, varscan2
- PPP1R3A | c.2899C>A p.P967T | Missense Mutation (SNP) | VAF 11/309 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV52878387; called by muse, mutect2
- PTGFRN | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67797997; called by muse, mutect2, varscan2
- RTL3 | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV58183453; called by muse, mutect2, varscan2
- SESN1 | c.746G>A p.G249D (on ENST00000356644 / NM_001199933.1; = p.G308D on NM_014454.3) | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV57420426; called by muse, mutect2, varscan2
- SLC38A8 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs200233980; called by muse, mutect2
- SLC4A5 | c.2404C>G p.P802A | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61025428; called by muse, mutect2, varscan2
- SOS1 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs758546951, COSV67674195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ST3GAL6 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752775935, COSV54579603, COSV54581895; called by muse, mutect2, varscan2
- SYCP1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1487912091, COSV65694293; called by muse, mutect2, varscan2
- TACR3 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 151/460 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs202051644; called by muse, mutect2, varscan2
- TEX15 | c.3673G>A p.A1225T (on ENST00000256246; = p.A1608T on NM_001350162.2) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs751183439, COSV56342984; called by muse, mutect2, varscan2
- TLL2 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs755902799, COSV63571238, COSV63575180; called by muse, mutect2, varscan2
- TTN | c.52238A>T p.K17413M (on ENST00000591111; = p.K9989M on NM_003319.4) | Missense Mutation (SNP) | VAF 37/348 reads (11%) | PolyPhen probably damaging (0.999); catalogued as COSV59930722; called by muse, mutect2, varscan2
- XKR7 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs758370039, COSV73812931; called by muse, mutect2, varscan2
- ZNF79 | c.402G>C p.E134D | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); catalogued as COSV61070565; called by muse, mutect2
- TRBV2 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ANK3 | c.4593G>A p.T1531= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as rs746128899, COSV55044280; called by muse, mutect2, varscan2
- CLCN7 | c.1767C>T p.T589= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs369837981; called by muse, varscan2
- GIMAP8 | c.912G>A p.P304= | Silent (SNP) | VAF 48/248 reads (19%) | catalogued as rs768970689, COSV56230233; called by muse, mutect2, varscan2
- IBTK | c.2082T>G p.V694= | Silent (SNP) | VAF 68/228 reads (30%) | catalogued as COSV60391476; called by muse, mutect2, varscan2
- IGFLR1 | c.663C>T p.G221= | Silent (SNP) | VAF 90/295 reads (31%) | catalogued as rs377303186; called by muse, mutect2, varscan2
- KRT8 | c.657C>T p.D219= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as rs766149578, COSV53176260; called by muse, mutect2, varscan2
- MAT2B | c.963T>G p.P321= | Silent (SNP) | VAF 15/170 reads (9%) | catalogued as rs199689662, COSV55200329; called by muse, mutect2
- OAZ1 | c.222C>T p.P74= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs755649263, COSV59233025; called by muse, mutect2, varscan2
- SBNO1 | c.3378G>A p.A1126= (on ENST00000420886; = p.A1125= on NM_018183.5) | Silent (SNP) | VAF 79/316 reads (25%) | catalogued as rs145298684, COSV57339549; called by muse, mutect2, varscan2
- ZNF804B | c.3951A>G p.V1317= | Silent (SNP) | VAF 18/427 reads (4%) | catalogued as COSV60819972; called by muse, mutect2
- FAM74A3 | n.365G>A | RNA (SNP) | VAF 30/199 reads (15%) | catalogued as rs1275849448; called by muse, mutect2, varscan2
